Somatic mutation profile of tumor specimen TCGA-SC-AA5Z-01A (aliquot TCGA-SC-AA5Z-01A-21D-A39R-32) from TCGA case TCGA-SC-AA5Z, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 54.1 years (19,746 days).
Specimen TCGA-SC-AA5Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55e1ec40-e53a-4b84-ba7c-d54e7087b509.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SC-AA5Z-10A (Blood Derived Normal), aliquot TCGA-SC-AA5Z-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e507da38-86d8-41f7-aa50-74a7e01fd826

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCDHA8 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as rs782317830, COSV100970840; called by muse, mutect2, varscan2
- SLCO1A2 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs200073343, COSV56598643; called by muse, mutect2, varscan2
- TRMT1L | c.277A>G p.N93D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1183255357; called by muse, mutect2, varscan2
- ANKRD50 | c.2951A>T p.H984L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- BRWD3 | c.1534G>C p.G512R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC2I1 | c.2147C>T p.T716I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- IFITM3 | c.323T>G p.I108S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MCM9 | c.543dup p.K182* | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- NF2 | c.558_561del p.R187Lfs*21 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- OR5W2 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMURF1 | c.1144C>G p.L382V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- SMURF1 | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLINT1 | c.900A>G p.P300= | Silent (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- FAT3 | c.10536A>G p.T3512= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, varscan2
- HPS4 | c.1560C>T p.P520= | Silent (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- SARDH | c.903C>T p.I301= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs200130370, COSV53834491; called by muse, mutect2, varscan2
